Somatic mutation profile of tumor specimen C3L-06364-54 (aliquot CPT0345720002) from CPTAC case C3L-06364, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 47.1 years (17,216 days).
Specimen C3L-06364-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fb3ed3c-6d71-482d-ab63-c9e27bf6ac9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06364-50 (Buccal Cell Normal), aliquot CPT0345690003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0739b7d0-93c4-4082-aebe-2f1192c29969

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NR1H4 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV51850964; called by muse, mutect2, varscan2
- TAF1B | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs926311334; called by muse, mutect2, varscan2
- DOCK3 | c.4903A>T p.K1635* | Nonsense Mutation (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- FBXL13 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GABPB1 | c.698C>G p.A233G | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- IMMT | c.799G>C p.G267R | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); called by muse, mutect2
- ENPP1 | c.762A>T p.T254= | Silent (SNP) | VAF 17/288 reads (6%) | called by muse, mutect2
- COL4A5 | c.3246+12C>G | Intron (SNP) | VAF 19/207 reads (9%) | called by muse, mutect2
- KLHL7 | c.*308T>A | 3'UTR (SNP) | VAF 22/364 reads (6%) | called by muse, mutect2
